Somatic mutation profile of tumor specimen TCGA-A6-2677-01A (aliquot TCGA-A6-2677-01A-01D-A270-10) from TCGA case TCGA-A6-2677, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 68.8 years (25,143 days).
Specimen TCGA-A6-2677-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3c40251-7859-43bd-9b2f-b4c5ce03b689.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-2677-10A (Blood Derived Normal), aliquot TCGA-A6-2677-10A-01D-A270-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a7b14ac-ba94-4be3-b385-fbcd58f6d688

The open-access MAF lists 149 somatic variants for this specimen: 103 protein-altering or splice-affecting, 45 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 45, Nonsense Mutation 7, Frame Shift Del 4, Frame Shift Ins 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4463del p.L1488Yfs*19 | Frame Shift Del (DEL) | VAF 34/91 reads (37%) | catalogued as rs1114167577, COSV57389473; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 62/125 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.3463G>A p.V1155I | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.078); catalogued as rs759961510, COSV100216771; called by muse, mutect2, varscan2
- ABHD18 | c.1186C>T p.R396* (on ENST00000398965 / NM_001039717.2; = p.R303* on NM_025097.2 and 10 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 68/156 reads (44%) | catalogued as rs149965291; called by muse, mutect2, varscan2
- ABL1 | c.2483C>T p.S828L | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.079); catalogued as rs762470102, COSV100583574; called by muse, mutect2, varscan2
- ABR | c.1204C>T p.R402W (on ENST00000302538 / NM_021962.5; = p.R365W on NM_001092.5) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs979862986, COSV52151984; called by muse, mutect2, varscan2
- ACAN | c.672G>T p.K224N | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100717323; called by muse, mutect2
- ACR | c.1033C>T p.R345* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | catalogued as rs1384373386, COSV99334373; called by muse, mutect2, varscan2
- ACTL7B | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs764432169, COSV65927155; called by muse, mutect2, varscan2
- AMY2A | c.752A>T p.D251V | Missense Mutation (SNP) | VAF 81/334 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70214384; called by muse, mutect2, varscan2
- AP1M2 | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs1202522150, COSV51566479, COSV51568642, COSV99140743; called by muse, mutect2, varscan2
- APC | c.1438C>T p.Q480* | Nonsense Mutation (SNP) | VAF 31/67 reads (46%) | catalogued as CM040977, COSV57355920; called by muse, mutect2, varscan2
- APLP1 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375567499; called by muse, mutect2, varscan2
- ARHGAP15 | c.456C>A p.S152R | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as rs1172005459, COSV99709041; called by muse, mutect2, varscan2
- ARHGEF9 | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); catalogued as rs781858542, COSV53634623; called by muse, mutect2, varscan2
- ATRX | c.2312C>T p.A771V | Missense Mutation (SNP) | VAF 113/204 reads (55%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as rs376906761, COSV64874330; called by muse, mutect2, varscan2
- AXL | c.2162T>C p.L721P (on ENST00000301178 / NM_021913.5; = p.L712P on NM_001699.6) | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99996087; called by muse, mutect2, varscan2
- BMP5 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 108/231 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752442881, COSV63702034; called by muse, mutect2, varscan2
- BTBD10 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV99533405; called by muse, mutect2, varscan2
- C1R | c.1987G>A p.A663T (on ENST00000536053 / NM_001354346.2; = p.A649T on NM_001733.7) | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT tolerated (0.71); PolyPhen benign (0.111); catalogued as rs1232507665, COSV73383043; called by muse, mutect2, varscan2
- C6 | c.2308A>C p.K770Q | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV99666657; called by muse, mutect2
- CALCRL | c.985A>C p.N329H | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs1018639295, COSV101130893; called by muse, mutect2, varscan2
- COL4A4 | c.4148G>T p.G1383V | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100306388; called by muse, mutect2, varscan2
- COL6A3 | c.6869G>A p.R2290H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs398124131, COSV99796521; ClinVar: uncertain significance; called by muse, mutect2
- CYP3A7 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 56/105 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as rs760875340, COSV60480907; called by muse, mutect2, varscan2
- DSE | c.2147G>A p.R716H | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs549153887, COSV59065405; called by muse, mutect2, varscan2
- DSEL | c.2768G>A p.S923N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.22); catalogued as COSV100025354, COSV59490768; called by muse, mutect2, varscan2
- EXOSC10 | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT tolerated (0.11); PolyPhen benign (0.34); catalogued as rs1176642616, COSV58665211; called by muse, mutect2, varscan2
- FAT3 | c.4564G>A p.E1522K | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as rs748097452, COSV53094893, COSV99971876; called by muse, mutect2, varscan2
- FOXI2 | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV59094132; called by muse, mutect2, varscan2
- GRIP2 | c.3280C>T p.R1094W (on ENST00000619221; = p.R997W on NM_001080423.4) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs765627113, COSV99817033; called by mutect2, varscan2
- HIVEP2 | c.3357G>A p.W1119* | Nonsense Mutation (SNP) | VAF 3/30 reads (10%) | catalogued as COSV50005422; called by muse, mutect2
- HTR1E | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1222836067, COSV59508189, COSV59511573; called by muse, mutect2, varscan2
- HYDIN | c.7531C>T p.R2511W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774441724, COSV99992170; called by muse, mutect2, varscan2
- IFI35 | c.144C>G p.I48M | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.246); catalogued as COSV55896797, COSV99887721; called by muse, mutect2, varscan2
- IGFBP3 | c.683A>G p.N228S | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.255); catalogued as rs1284105182, COSV99298211; called by muse, mutect2, varscan2
- INPPL1 | c.2627C>T p.T876M | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.353); catalogued as rs367743824; called by muse, mutect2, varscan2
- IRAG1 | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as rs374041885; called by muse, mutect2
- KLF8 | c.1039G>C p.D347H | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100808138; called by muse, mutect2, varscan2
- KLHL13 | c.1305C>G p.H435Q | Missense Mutation (SNP) | VAF 67/148 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.044); catalogued as COSV99451198; called by muse, mutect2, varscan2
- KLHL15 | c.20G>C p.G7A | Missense Mutation (SNP) | VAF 71/174 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV100044023; called by muse, mutect2, varscan2
- KLK4 | c.490G>A p.V164M | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.847); catalogued as rs777659052, COSV100133555; called by muse, mutect2, varscan2
- MCM10 | c.659G>A p.R220Q (on ENST00000484800 / NM_182751.3; = p.R219Q on NM_018518.5) | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as rs756598324, COSV66333712; called by muse, mutect2, varscan2
- MYT1 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV100114130; called by muse, varscan2
- NANOG | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.263); catalogued as COSV57551161; called by muse, mutect2, varscan2
- NBEAL2 | c.5336G>A p.R1779H | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1393928806, COSV99434819; called by muse, mutect2, varscan2
- NDST3 | c.1885A>C p.K629Q | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.589); catalogued as COSV99629840; called by muse, mutect2, varscan2
- NDUFAF3 | c.371A>G p.E124G | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as COSV100454961; called by muse, mutect2, varscan2
- NES | c.3751G>C p.G1251R | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.727); catalogued as COSV100957780; called by muse, mutect2, varscan2
- NKX2-1 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as CM136275, COSV61388050, COSV61390583; called by muse, mutect2
- NME9 | c.223G>A p.E75K (on ENST00000333911 / NM_001349024.2; = p.E53K on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.06); catalogued as rs200732318, COSV58616706; called by muse, mutect2, varscan2
- NOVA1 | c.1358C>A p.A453E | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99946754; called by muse, mutect2, varscan2
- NRK | c.2185C>T p.R729C | Missense Mutation (SNP) | VAF 154/288 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs779676790, COSV54598219; called by muse, mutect2, varscan2
- OR1D5 | c.551T>C p.L184P | Missense Mutation (SNP) | VAF 64/94 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770608969, COSV101643410; called by muse, mutect2, varscan2
- PCDHGA12 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.086); catalogued as rs747313827, COSV52745626; called by muse, mutect2, varscan2
- PCSK2 | c.4A>G p.K2E | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.027); catalogued as COSV99358901; called by muse, mutect2
- PIP5K1C | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.063); catalogued as rs748987470, COSV100095086; called by muse, mutect2, varscan2
- PKHD1 | c.4199C>T p.S1400L | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as rs191201723; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POGZ | c.3386C>A p.S1129Y | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51851084; called by muse, mutect2, varscan2
- PTPN13 | c.2759T>A p.L920H | Missense Mutation (SNP) | VAF 85/188 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV100364226; called by muse, mutect2, varscan2
- PTPN23 | c.3489C>A p.D1163E | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99650280; called by muse, varscan2
- PTPRD | c.2215A>C p.K739Q | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.574); catalogued as COSV100643790; called by muse, mutect2, varscan2
- RAD18 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs769975828, COSV53748856; called by muse, mutect2, varscan2
- RIMKLB | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as rs1424474258, COSV100223785; called by muse, mutect2, varscan2
- RPTOR | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 64/89 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1452445269, COSV60806260, COSV60808190; called by muse, mutect2, varscan2
- SACS | c.10832C>A p.A3611D | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101207233; called by muse, mutect2, varscan2
- SCGB3A1 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs773272977, COSV53005461; called by muse, mutect2, varscan2
- SERPINI1 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.99); PolyPhen benign (0.028); catalogued as COSV99854887; called by muse, mutect2, varscan2
- SHCBP1L | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.801); catalogued as COSV100840948; called by muse, mutect2, varscan2
- SLC12A1 | c.1845G>C p.L615F | Missense Mutation (SNP) | VAF 49/64 reads (77%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV101118336; called by muse, mutect2, varscan2
- SLC12A5 | c.2024C>T p.A675V (on ENST00000454036 / NM_001134771.2; = p.A652V on NM_020708.5) | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1555865828, COSV99715498; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC35F3 | c.631G>A p.A211T (on ENST00000366617 / NM_001300845.1; = p.A280T on NM_173508.4) | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs773044833, COSV64019679; called by muse, mutect2, varscan2
- SLITRK6 | c.296A>T p.N99I | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.235); catalogued as COSV101233188, COSV68390511; called by muse, mutect2
- SORCS1 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.535); catalogued as rs1262994826, COSV99544071; called by muse, mutect2, varscan2
- SOX11 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.527); catalogued as rs1411163388, COSV100430952, COSV58983614; called by muse, mutect2, varscan2
- SP140 | c.772G>T p.A258S | Missense Mutation (SNP) | VAF 61/148 reads (41%) | SIFT tolerated (0.76); PolyPhen benign (0.009); catalogued as rs1451524780, COSV59448267; called by mutect2, varscan2
- SPAG17 | c.5858C>T p.S1953F | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV100308242; called by muse, mutect2, varscan2
- SPRY3 | c.501C>G p.C167W | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57142427; called by muse, mutect2
- STRA8 | c.260G>A p.W87* (on ENST00000275764; = p.W65* on NM_182489.2) | Nonsense Mutation (SNP) | VAF 22/42 reads (52%) | catalogued as rs1290153678, COSV99312279; called by muse, mutect2, varscan2
- SULT6B1 | c.418C>T p.R140* (on ENST00000535679 / NM_001367551.1; = p.R102* on NM_001032377.2) | Nonsense Mutation (SNP) | VAF 25/63 reads (40%) | catalogued as rs147099571, COSV53194210; called by muse, mutect2
- SYNE1 | c.1108C>T p.Q370* (on ENST00000367255 / NM_182961.4; = p.Q377* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as COSV99555915; called by muse, mutect2, varscan2
- TAFA4 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs761271480, COSV55140944, COSV99806268; called by mutect2, varscan2
- TAS2R13 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.8); PolyPhen benign (0.03); catalogued as COSV101183721; called by muse, mutect2, varscan2
- TAS2R14 | c.19A>G p.S7G | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV67854403; called by muse, varscan2
- TBX22 | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as COSV100960655; called by muse, mutect2, varscan2
- TMEM185A | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 82/157 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100382959; called by muse, mutect2, varscan2
- TRIM55 | c.1438C>T p.R480W | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.153); catalogued as rs754147349, COSV52545616; called by muse, mutect2, varscan2
- TRMT11 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.077); catalogued as rs1253146421, COSV100543093; called by muse, mutect2, varscan2
- TTN | c.94499T>A p.L31500H (on ENST00000591111; = p.L24076H on NM_003319.4) | Missense Mutation (SNP) | VAF 23/55 reads (42%) | PolyPhen probably damaging (0.992); catalogued as COSV100598789; called by muse, mutect2, varscan2
- TUBE1 | c.1253G>A p.R418K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100036918; called by muse, mutect2, varscan2
- UGDH | c.418A>C p.I140L | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.248); catalogued as COSV100328393, COSV57100500; called by muse, mutect2, varscan2
- UNC5B | c.1540G>A p.D514N | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.5); PolyPhen benign (0.177); catalogued as rs202076199; called by muse, mutect2, varscan2
- WIPF1 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs770503150, COSV99768087; called by mutect2, varscan2
- ZFHX4 | c.2909A>G p.K970R | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.994); catalogued as COSV99258194; called by muse, mutect2, varscan2
- ZIC1 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.772); catalogued as COSV51553967, COSV51556822; called by muse, mutect2, varscan2
- ZNF260 | c.281A>G p.Q94R | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.084); catalogued as COSV101591032; called by muse, mutect2, varscan2
- ZNF484 | c.2165G>A p.C722Y | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100214500; called by muse, mutect2, varscan2
- ZNF658 | c.1118G>T p.R373I | Missense Mutation (SNP) | VAF 79/163 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs766547680; called by muse, varscan2
- ANK3 | c.13053dup p.S4352Vfs*2 (on ENST00000280772 / NM_001320874.2; = p.S976Vfs*2 on NM_001149.3) | Frame Shift Ins (INS) | VAF 25/58 reads (43%) | called by mutect2, pindel, varscan2
- KARS1 | c.18_20del p.A7del | In Frame Del (DEL) | VAF 10/42 reads (24%) | called by pindel, varscan2
- OR6S1 | c.96_97del p.F33Sfs*21 | Frame Shift Del (DEL) | VAF 20/61 reads (33%) | called by pindel, varscan2
- SOX9 | c.729_736delinsA p.D244Sfs*7 | Frame Shift Del (DEL) | VAF 80/141 reads (57%) | called by pindel, varscan2*
- ZC3H13 | c.2274_2283del p.R758Sfs*104 | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | called by mutect2, varscan2
- ADCY1 | c.2289C>T p.Y763= | Silent (SNP) | VAF 39/78 reads (50%) | catalogued as rs369554390; called by muse, mutect2, varscan2
- ARMC5 | c.930C>T p.A310= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as COSV99192352; called by muse, mutect2, varscan2
- AS3MT | c.1101C>T p.G367= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV100185601; called by muse, mutect2, varscan2
- BOP1 | c.1302C>T p.D434= | Silent (SNP) | VAF 18/20 reads (90%) | catalogued as rs1051626478; called by muse, mutect2, varscan2
- CELSR1 | c.3273C>T p.L1091= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as rs752003469, COSV99417142; called by muse, mutect2, varscan2
- CEP350 | c.2031A>G p.Q677= | Silent (SNP) | VAF 37/60 reads (62%) | catalogued as COSV62600577; called by muse, mutect2, varscan2
- DKKL1 | c.348G>A p.E116= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV55564050, COSV99678630; called by muse, mutect2, varscan2
- DNM1 | c.1911C>T p.S637= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs1244508469, COSV100359597; called by muse, varscan2
- EGR1 | c.1440G>A p.S480= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV53518683; called by muse, mutect2, varscan2
- EPHX1 | c.690G>A p.L230= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as rs1431236139, COSV55299140, COSV99688778; called by muse, mutect2, varscan2
- FLNC | c.5361G>T p.L1787= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100367716; called by mutect2, varscan2
- GPR25 | c.297G>A p.A99= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV58497899; called by muse, mutect2, varscan2
- HELQ | c.192G>A p.Q64= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as rs1178892854, COSV55024416; called by muse, mutect2, varscan2
- IL22RA2 | c.417G>A p.S139= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as rs140915731; called by muse, mutect2, varscan2
- ITGA10 | c.1392G>A p.Q464= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV100994760; called by muse, mutect2, varscan2
- KIAA1210 | c.3741T>C p.P1247= | Silent (SNP) | VAF 26/44 reads (59%) | catalogued as rs746934065, COSV101273956; called by muse, mutect2, varscan2
- KIAA1614 | c.2739G>A p.P913= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs376502384; called by muse, mutect2, varscan2
- KNDC1 | c.3306C>T p.C1102= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as COSV100463668; called by muse, varscan2
- LAMC3 | c.915G>T p.L305= | Silent (SNP) | VAF 42/95 reads (44%) | catalogued as COSV63096733; called by muse, mutect2
- MED12 | c.1920T>C p.P640= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV61336149; called by muse, mutect2
- MYO3A | c.3448A>C p.R1150= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV99778693; called by muse, mutect2
- NDN | c.108G>A p.A36= | Silent (SNP) | VAF 19/23 reads (83%) | catalogued as COSV59359485, COSV59359551; called by muse, mutect2, varscan2
- NLRP4 | c.699C>T p.F233= | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as rs577037043, COSV56708587; called by muse, mutect2, varscan2
- NPTX1 | c.1251C>T p.Y417= | Silent (SNP) | VAF 62/83 reads (75%) | catalogued as rs768903811, COSV60774392; called by muse, mutect2, varscan2
- PCDH10 | c.939C>T p.S313= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs769286962, COSV99993129; called by muse, mutect2, varscan2
- PCDHA9 | c.1974G>A p.A658= | Silent (SNP) | VAF 43/100 reads (43%) | catalogued as rs782339078, COSV65333380; called by muse, mutect2, varscan2
- PCDHB15 | c.1581C>T p.F527= | Silent (SNP) | VAF 76/176 reads (43%) | catalogued as rs782103267, COSV50929775; called by muse, mutect2, varscan2
- PCDHB6 | c.471C>T p.H157= | Silent (SNP) | VAF 28/53 reads (53%) | catalogued as COSV50692043; called by muse, mutect2, varscan2
- PCDHB6 | c.2172G>A p.S724= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV50690061; called by muse, mutect2, varscan2
- PGF | c.375C>T p.H125= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as rs749171908, COSV53125108; called by muse, mutect2, varscan2
- PKP2 | c.597C>A p.I199= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV50727106, COSV50728255; called by muse, mutect2, varscan2
- POTEA | c.114C>T p.S38= | Silent (SNP) | VAF 48/103 reads (47%) | called by muse, mutect2, varscan2
- SELENOM | c.399G>A p.A133= | Silent (SNP) | VAF 36/73 reads (49%) | catalogued as COSV100294083; called by muse, mutect2, varscan2
- SLC24A2 | c.594C>T p.I198= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs758224147, COSV53865048; called by muse, mutect2, varscan2
- SPA17 | c.27C>T p.H9= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as rs368335369; called by muse, mutect2, varscan2
- STAB2 | c.6552C>T p.D2184= | Silent (SNP) | VAF 26/29 reads (90%) | catalogued as rs577176538, COSV66335510; ClinVar: likely benign; called by muse, mutect2, varscan2
- STIM2 | c.2169C>T p.D723= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV99402205; called by muse, mutect2, varscan2
- SUV39H1 | c.837C>T p.T279= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV100551696; called by mutect2, varscan2
- SYT14 | c.1626A>G p.K542= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV99654746; called by muse, mutect2
- TMEM132D | c.1593C>T p.S531= | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as rs376143160; called by muse, mutect2, varscan2
- TMEM63B | c.477C>T p.I159= | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as rs1383525673, COSV99441138; called by muse, mutect2, varscan2
- TNFAIP6 | c.465C>T p.Y155= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as rs755909985, COSV54639916; called by muse, mutect2, varscan2
- TNXB | c.4434G>A p.A1478= (on ENST00000647633; = p.A1231= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as rs369459090; called by muse, mutect2, varscan2
- TPCN1 | c.1665C>T p.N555= | Silent (SNP) | VAF 34/40 reads (85%) | catalogued as rs538285886, COSV59237638; called by muse, mutect2, varscan2
- ZNF236 | c.4104G>A p.L1368= | Silent (SNP) | VAF 35/44 reads (80%) | catalogued as COSV99469447; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840271 C>T | 5'Flank (SNP) | VAF 60/91 reads (66%) | catalogued as COSV58345870; called by muse, mutect2, varscan2
